BEATAML1.0 case 2459 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myelodysplastic Syndromes; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/8db4ef4f-b1b7-4d27-94f4-afd6f29c4da3

Demographics
Sex at birth: female.

Diagnoses (1)
1. Myelodysplastic syndrome, unclassifiable: ICD-O-3 morphology code: 9989/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 40.2 years (14,694 days); Progression or recurrence: no; ELN risk classification: Intermediate.

Biospecimens (2 samples)
- Sample BA2071D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
- Sample BA2983D: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
